Somatic mutation profile of tumor specimen MMRF_2478_1_BM_CD138pos (aliquot MMRF_2478_1_BM_CD138pos_T1_KHS5U_L11632) from MMRF case MMRF_2478, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.2 years (19,060 days).
Specimen MMRF_2478_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2021cd80-f2e3-478b-9b36-fc8ace1301f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2478_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2478_1_PB_Whole_C3_KHS5U_L11633; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29910c8c-c16e-4f54-98d6-996286743d2b

The open-access MAF lists 57 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, 3'UTR 16, Silent 8, Intron 5, 5'UTR 4, 3'Flank 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 116/336 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 135/292 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs202216589; called by muse, varscan2
- ACSM4 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772224561, COSV68068600; called by muse, mutect2, varscan2
- ATP6V1A | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56360753; called by muse, mutect2, varscan2
- GYS1 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as rs897471867; called by muse, mutect2, varscan2
- GYS1 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 139/267 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as rs370035815; called by muse, mutect2, varscan2
- H1-4 | c.189G>C p.K63N | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56800659, COSV99175386; called by muse, mutect2, varscan2
- IGLV3-1 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 126/238 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as rs569422572; called by muse, varscan2
- IGLV3-1 | c.320A>T p.Q107L | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs192317432; called by muse, varscan2
- PKD1L1 | c.3239C>T p.A1080V | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs767012711; called by muse, mutect2, varscan2
- RAB22A | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as rs765175475; called by muse, mutect2, varscan2
- SLC26A8 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.278); catalogued as rs772520541, COSV62885581, COSV62885594; called by muse, mutect2, varscan2
- SLC6A4 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs140484986; called by muse, mutect2, varscan2
- ZFHX4 | c.4265G>A p.R1422Q | Missense Mutation (SNP) | VAF 102/275 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764104033, COSV50479876, COSV51492245, COSV99262664; called by muse, mutect2, varscan2
- CDHR3 | c.1187G>T p.R396I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- FMN1 | c.1804A>G p.T602A | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV3-1 | c.64_82del p.E22Qfs*64 | Frame Shift Del (DEL) | VAF 64/115 reads (56%) | called by pindel, varscan2
- LTB | c.211T>C p.F71L | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, varscan2
- MACF1 | c.13544C>A p.A4515D (on ENST00000372915; = p.A2448D on NM_012090.5) | Missense Mutation (SNP) | VAF 56/131 reads (43%) | called by muse, mutect2, varscan2
- NR3C2 | c.256T>G p.S86A | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.05); called by muse, varscan2
- PIGZ | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- RYR1 | c.7216T>A p.F2406I | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- CHPF2 | c.678C>A p.G226= | Silent (SNP) | VAF 102/228 reads (45%) | called by muse, mutect2, varscan2
- GRIN2C | c.1623C>T p.T541= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as rs145450475; called by muse, mutect2, varscan2
- IGHV2-70 | c.57C>G p.S19= | Silent (SNP) | VAF 49/56 reads (88%) | catalogued as rs554480066; called by muse, mutect2, varscan2
- KRT7 | c.904C>A p.R302= | Silent (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- PVR | c.498C>T p.C166= | Silent (SNP) | VAF 48/105 reads (46%) | catalogued as rs745519679; called by muse, mutect2, varscan2
- RNF31 | c.159C>T p.A53= | Silent (SNP) | VAF 51/99 reads (52%) | called by muse, mutect2, varscan2
- SLC38A10 | c.1692C>A p.A564= | Silent (SNP) | VAF 121/270 reads (45%) | called by muse, mutect2, varscan2
- TRABD2B | c.1185C>T p.T395= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1001400967, COSV71110077; called by muse, mutect2, varscan2
- ATOX1 | chr5:151742466 G>C | 3'Flank (SNP) | VAF 6/129 reads (5%) | called by muse, mutect2
- CAMKV | c.96-9C>T | Intron (SNP) | VAF 17/323 reads (5%) | catalogued as rs536810134; called by muse, mutect2
- CCNA1 | c.-90A>C | 5'UTR (SNP) | VAF 172/405 reads (42%) | called by muse, mutect2, varscan2
- CDK10 | chr16:89682382 G>A | 5'Flank (SNP) | VAF 32/71 reads (45%) | catalogued as rs1417261621; called by muse, mutect2, varscan2
- DAPK1 | c.1825-81C>G | Intron (SNP) | VAF 77/189 reads (41%) | called by muse, mutect2, varscan2
- DENND6B | c.*18C>T | 3'UTR (SNP) | VAF 10/102 reads (10%) | catalogued as rs756948906; called by muse, mutect2
- DESI2 | c.*2612C>T | 3'UTR (SNP) | VAF 39/93 reads (42%) | catalogued as rs942795917; called by muse, mutect2, varscan2
- DGKB | c.*836G>T | 3'UTR (SNP) | VAF 69/159 reads (43%) | called by muse, mutect2, varscan2
- IL1R1 | c.*512del | 3'UTR (DEL) | VAF 79/244 reads (32%) | called by mutect2, pindel, varscan2
- IRF2BP2 | c.*2287C>G | 3'UTR (SNP) | VAF 45/139 reads (32%) | called by muse, mutect2, varscan2
- LTB | c.208+82C>G | Intron (SNP) | VAF 47/117 reads (40%) | catalogued as rs566098575; called by muse, mutect2, varscan2
- NACC2 | c.*3446G>A | 3'UTR (SNP) | VAF 77/144 reads (53%) | catalogued as rs1451702700; called by muse, mutect2, varscan2
- NEURL1B | c.*3448G>T | 3'UTR (SNP) | VAF 46/134 reads (34%) | called by muse, mutect2, varscan2
- OTOR | c.*544T>C | 3'UTR (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
- PPP2R5C | c.1327-14G>A | Intron (SNP) | VAF 5/37 reads (14%) | catalogued as rs890004318, COSV58269686; called by muse, mutect2, varscan2
- PTPRS | c.-17G>A | 5'UTR (SNP) | VAF 66/136 reads (49%) | catalogued as rs372198679; called by muse, mutect2, varscan2
- RTP1 | c.*241_*243del | 3'UTR (DEL) | VAF 43/92 reads (47%) | called by mutect2, pindel, varscan2
- SHPRH | c.*611G>T | 3'UTR (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- SLC22A3 | c.*329T>C | 3'UTR (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- SLC28A1 | c.461+486G>A | Intron (SNP) | VAF 33/56 reads (59%) | catalogued as rs1223099628; called by muse, mutect2, varscan2
- SLC6A5 | c.*2728G>C | 3'UTR (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- SULT1C4 | c.-59G>C | 5'UTR (SNP) | VAF 46/108 reads (43%) | called by muse, mutect2, varscan2
- SYTL5 | c.*344C>A | 3'UTR (SNP) | VAF 32/43 reads (74%) | called by muse, mutect2, varscan2
- TSR2 | c.*822C>T | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- TUBA4A | c.-26C>G | 5'UTR (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- USP47 | c.*2682T>C | 3'UTR (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- ZNF696 | c.*266C>T | 3'UTR (SNP) | VAF 32/87 reads (37%) | catalogued as rs995448464; called by muse, mutect2, varscan2
